CPTAC case GTEX-QVJO-0011-R10A-SM-HAKXV — Brain (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/45829e3e-e08d-4c7e-85bb-a6e7b4baa208

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Dead; Days to death: 0 days.

Exposures
- Alcohol history: No.

Biospecimens (1 sample)
- Sample PT-QVJO-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2.
